FM case AD586 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/d25c5b34-9f7d-46b4-b51f-c7361009dbd6

Female, 49.1 years: Infiltrating duct carcinoma, NOS (ICD-O-3 8500/3) of the breast; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
